Surgical pathology report (de-identified scan), TCGA case TCGA-06-2564, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2564-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

TCGA-06-2564

CLINICAL HISTORY

experienced a seizure and on MRI has a hemorrhagic lesion in the right frontal lobe, non-enhancing on previous CT scan. There is associated vasogenic edema and some subfalcine herniation.

OPERATIVE DIAGNOSES

Right frontal brain mass

Operation/Specimen: A: Brain, Right frontal lesion, excision biopsy
: Brain, right frontal, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, right frontal, excision:
1. Glioblastoma, with recent hemorrhage.
2. MIB-1 proliferation index: 60%.
See Microscopy Description and Comment.

COMMENT

The specimens are fragments of cerebrum that are infiltrated and extensively effaced by a glial neoplastic proliferation that has proclivity for the white matter. The neoplastic cells are small, elongated naked nuclei. There is brisk mitotic activity with a very high proliferation index of about 60%. There is prominent microvascular cellular proliferation and zones of tumor necrosis, some with pseudopalisading. Within the tumor and adjacent brain tissue there is recent hemorrhage.

The morphology and immunophenotype are characteristic of a glioblastoma that has undergone recent bleeding.

PROCEDURES/ADDENDA
MGMT Promoter Methylation

[page 2 of 4]
Interpretation

EGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]

Interpretation

POSITIVE - EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] Pathology laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

[page 3 of 4]
INTRA-OPERATIVE CONSULTATION

A.
Brain, Right frontal lesion, excision biopsy, touch prep and smears:
Malignant neoplasm, fibrillary (C/W glioblastoma). Touch preparation smears
performed at [REDACTED] and results reported to the Physician of
Record. [REDACTED]

GROSS DESCRIPTION

A.
SPECIMEN: Right frontal brain mass
FIXATIVE: None
GENERAL: A 3.0 x 2.0 x 0.6 cm aggregate of multiple irregularly shaped red to
gray tan fragments of brain tissue. Preps and smears made by [REDACTED]
SECTIONS: A1-3 all submitted.

B.
SPECIMEN: Right frontal tumor
FIXATIVE: Formalin
GENERAL: A 7 cm irregular fragment of gray white tan brain tissue. A 1-2 mm
tan fragment is submitted.
SECTIONS: B1-largest fragment bisected.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a heavy gliofibrillary background
within the glial neoplastic proliferation. A majority of neoplastic cells
over express the p53 protein. The CD163 depicts frequent activated microglia
around and within the neoplastic cells. With the MIB-1 there is a
proliferation index of about 60% throughout the tumor.

ICD-9(s):
191.9 191.9

Histo Data

rt A: Brain, Right frontal lesion, excision biopsy

Stain/Chl	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

[page 4 of 4]
[REDACTED]

TPS H/E x 1	1
CD163 Vector x 1	2
GFR vIII-curls x 1	2
mGFAP-DA x 1	2
H/E x 1	2
MGMT-curls x 1	2
MIB1-DA x 1	2
P53DO7 x 1	2
H/E x 1	3

Part B: Brain right frontal excision biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 5c6e2526-eb43-411a-99b2-b9ad63521bf0 (TCGA-06-2564.D89F8307-B898-47AC-957B-A9B76F58BD01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).